Surgical pathology report (de-identified scan), TCGA case TCGA-3A-A9IZ, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Moffitt Cancer Center, specimen TCGA-3A-A9IZ-01A (Primary Tumor).

[page 1 of 6]
Pathology Report

ICD O-3

Adenocarcinoma, duct NOS
850013

Site Pancreas head
C25.0

JW 4/16/14

Final Diagnosis

- A. LIVER, BIOPSY:
Cholestasis with bile plugs, and steatosis, negative for carcinoma.
- B. LYMPH NODE, BIOPSY:
Bile infarct with foreign body giant cells, cholestasis with bile plugs, suggestive of large duct obstruction
Thick wall vessels present
- C. NODULE, PERIPHERAL, BIOPSY:
Adipose tissue with fibrosis and giant cell reaction with bile.
Negative for malignancy.
- D. SOFT TISSUE, PORTAL, BIOPSY:
Adipose tissue with histiocytes, negative for carcinoma
- E. LIVER, LEFT LATERAL LOBE, BIOPSY:
Liver with cholestasis and bile plugs.
- F. LIVER, LEFT LATERAL LIVER LOBE NODULE, BIOPSY:
Cholestasis, with bile plugs, consistent with large duct obstruction
- G. LIVER, LEFT LATERAL LIVER LOBE NODULE, DEEP BIOPSY:
Cholestasis and giant cells.
- H. LIVER, LEFT LATERAL NODULE, DEEP, BIOPSY:
Fibrous tissue and hepatic parenchyma with cholestasis and bile plugs, consistent with large duct obstruction.
- I. LIVER, SEGMENT 8 NODULE, BIOPSY:
Cholestasis, with bile plugs, consistent with large duct obstruction
- J. LIVER, SEGMENT 8 NODULE, BIOPSY:
Cholestasis, with bile plugs, consistent with large duct obstruction

[page 2 of 6]
- K. LIVER, SEGMENT 8 NODULE NO. 2, CORE BIOPSY:
Cholestasis, with bile plugs and focal cholangitis, consistent with large duct obstruction
- L. LYMPH NODE, SUPERIOR PANCREATIC NECK, BIOPSY:
One lymph node free of metastatic disease (0/1)
- M. HEAD OF PANCREAS, PORTION OF DUODENUM AND STOMACH:
Adenocarcinoma, well differentiated, invasive into adjacent peripancreatic tissue.
Tumor size: 4.0 cm.
Carcinoma is present on the portal vein groove surface and the superior mesenteric artery margin.
Extensive perineural invasion is identified.
Lymphovascular invasion identified.
Ampullary adenoma identified.
Adjacent pancreas with PanIN 2
Metastatic carcinoma to 3 of 20 lymph nodes (3/20)
See synoptic report.

I, _____ the attending pathologist, personally reviewed all slides and / or materials and rendered the final diagnosis. Electronically Signed Out by _____

Key Pathological Findings

A: Pancreas Exocrine

SPECIMEN:

Head of pancreas
Duodenum
Stomach

PROCEDURE:

Pancreaticoduodenectomy (Whipple resection), partial pancreatectomy

TUMOR SITE:

Pancreatic head

TUMOR SIZE:

Greatest dimension of solid component: 4.0 cm

HISTOLOGIC TYPE:

Ductal adenocarcinoma

HISTOLOGIC GRADE:

G2: Moderately differentiated

MICROSCOPIC TUMOR EXTENSION:

Tumor invades peripancreatic soft tissues

MARGINS:

Margin(s) involved by invasive carcinoma
Superior mesenteric artery
Portal vein groove

TREATMENT EFFECT (applicable to carcinomas treated with neoadjuvant therapy):

No prior treatment

LYMPH-VASCULAR INVASION:

[page 3 of 6]
Present
PERINEURAL INVASION:
Present
PRIMARY TUMOR (pT):
pT3: Tumor extends beyond the pancreas but without involvement of the celiac axis or the superior mesenteric artery
REGIONAL LYMPH NODES (pN):
pN1: Regional lymph node metastasis
Number examined: 21
Number involved: 3
DISTANT METASTASIS (pM):
pM0: No Distant metastasis
ADDITIONAL PATHOLOGIC FINDINGS:
Pancreatic intraepithelial neoplasia (highest grade: PanIN 2)
Acute pancreatitis
Pancreatitis with focal fat necrosis and giant cell reaction
CLINICAL HISTORY:
Not specified

Specimen(s) Received

A LIVER LESION FS
B LEFT LIVER BX FS
C PERIPORTAL TISSUE FS
D PERIPORTAL TISSUE
E LEFT LATERAL LIVER NODULE FS
F LEFT LATERAL LIVER LOBE NODULE
G LEFT LATERAL LIVER LOBE NODULE DEEP FS
H LEFT LATERAL LIVER LOBE NODULE DEEP
I SEGMENT 8 NODULE
J SEGMENT 8 NODULE FS
K SEGMENT 8 NODULE #2 FS
L SUPERIOR NECK PANCREAS LYMPH NODES
M WHIPPLE FS

Clinical History

None given.

Preoperative Diagnosis

Pancreatic cancer.

Intraoperative Consultation

FSA1/FSA2 LIVER LESION:
Giant cell granuloma, no evidence of malignancy.

FSB1 LEFT NODULE BIOPSY:
Fibrosis with thick wall vessels suggestive of vascular malformation.

FSC PERIPHERAL NODE:

[page 4 of 6]
Giant cell granulomatous reaction with segment of nerve and smooth muscle.
No evidence of malignancy.

- FSE1 LEFT LATERAL LIVER NODULE:
Liver, no evidence of malignancy.
- FSG1 LEFT LATERAL LOBE NODULES DEEP LIVER:
No evidence of malignancy.
- FSJ SEGMENT 8 NODULE:
No evidence of malignancy.
- FSK1 SEGMENT 8 NODULE 2:
No evidence of malignancy.
- FSM1 PANCREATIC MARGIN:
No evidence of malignancy.
- FSM2 CYST MARGIN:
No evidence of malignancy.

Comment: These frozen section diagnoses/results was/were communicated to and acknowledged by

I, _____, M.D., have performed the intraoperative consultation and issued the above diagnosis.

Gross Description

A. Specimen A is received fresh labeled "liver lesion." The specimen consists of an irregular tan-brown fragment of liver tissue measuring 2.6 x 1.6 x 1.0 cm. The margins of resection are inked black. The specimen is serially sectioned to reveal a tan-yellow and irregular possible lesion measuring 0.5 x 0.3 x 0.3 cm. Representative sections of the lesions are entirely submitted for frozen section diagnosis in FSA1-FSA2. The rest of the specimen is entirely submitted in cassettes labeled A3.

B. Specimen B is received fresh labeled "left liver nodule." The specimen consists of two cylindrical fragments of tan-brown liver cores measuring 2.2 cm in length and 1.2 cm in length respectively. Both 0.1 cm in greatest diameter. The specimen is entirely submitted for frozen section diagnosis as FSB1.

C. Specimen C is received fresh labeled "peripheral nodule." The specimen consists of an irregular fragment of soft tan-white to tan-pink tissue measuring 1.3 x 1.0 x 0.4 cm. The specimen is entirely submitted for frozen section diagnosis as FSC1.

D. Specimen D is received fresh labeled "periportal tissue." The specimen consists of un-oriented and irregular fragment of soft tan-white to tan-pink tissue measuring 2.0 x 1.8 x 1.0 cm. Revealing a tan-white cut surface grossly consistent with lymph node measuring 1.2 cm in greatest dimension. The specimen is entirely submitted in cassette D.

[page 5 of 6]
E. Specimen E is received fresh labeled "left lateral lobe nodule." The specimen consists of 2 tiny fragments of soft tan-white to tan-yellow tissue measuring 1.8 cm in length and 0.1 cm in diameter. The specimen is entirely submitted for frozen section diagnosis in cassette labeled FSE1.

F. Specimen F is received fresh labeled "left lateral liver lobe nodule." The specimen consists of cylindrical fragment of soft tan-brown tissue measuring 0.5 cm in length and 0.1 cm in greatest diameter. The specimen is entirely submitted in cassette F.

G. Specimen G is received fresh labeled "left lateral liver lobe nodule deep." The specimen consists of cylindrical fragment of soft tan-brown tissue measuring 0.3 cm in length and 0.1 cm in greatest diameter. The specimen is entirely submitted for frozen section diagnosis as FSG1.

H. Specimen H is received fresh labeled "left lateral liver nodule deep." The specimen consists of cylindrical fragment of soft tan-brown tissue measuring 1.5 cm in length and less than 0.1 cm in greatest diameter. The specimen is entirely submitted as H1.

I. Specimen I is received fresh labeled "segment 8 nodule." The specimen consists of cylindrical fragment of soft tan-white to tan-brown tissue measuring 1.2 cm in length and less than 0.1 cm in greatest diameter. The specimen is entirely submitted in cassette labeled I1.

J. Specimen J is received fresh labeled "segment 8 nodule." The specimen consists of fragment of tan soft tissue measuring 1.8 cm in length and 0.1 cm in greatest dimension. The specimen is entirely submitted for frozen section diagnosis in cassette labeled FSJ1.

K. Specimen K is received fresh labeled "segment 8 nodule #2." The specimen consists of tan soft fragment of tissue measuring 1.9 cm in length and 0.1 cm in greatest diameter. The specimen is entirely submitted for frozen section diagnosis as FSK1.

L. Specimen L is received fresh labeled "superior neck pancreatic lymph node." The specimen consists of an irregular fragment of tan-white to tan-yellow tissue measuring 2.0 x 1.2 x 0.7 cm. The specimen is bisected revealing a tan-white lymph node measuring 1.2 cm in greatest dimension. The lymph node is entirely submitted in 1 cassette as follows:

L1: One bisected lymph node

M. Specimen M is received fresh labeled "Whipple." The specimen consists of Whipple specimen and oriented by the surgeon as follows: Single stitch bowel duct margin, double stitch at gastric margin, triple stitches pancreatic margin, 4 stitches retroperitoneal margins. The specimen is inked as follows: Portal vein margin is inked with red, superior mesenteric artery margin is inked in black, Posterior surface inked orange. Attached to the specimen there is the head of pancreas, portion of duodenum, and portion of stomach. The gallbladder is not identified. The duodenum measures 13.0 cm in length. The serosa of the duodenum is smooth, tan to tan-red. On opening, the lumen does contain bile stained mucus. The mucosa of the duodenum and stomach does not reveal polyps or ulcers. The bile duct measures 6.5 cm in length and 2.0 cm in greatest diameter (dilated). Sectioning the pancreatic head, a solid tan-white mass with areas of necrosis is noted measuring 4.0 x 4.0 x 3.0 cm, located at 3.0 cm from bile duct margin of resection and less than 0.1 cm from portal vein margin of resection. The remaining pancreatic tissue is multilobulated, firm, and grossly unremarkable. The attached portion of stomach measures 11.0 cm along the greater curvature and 7.0 cm along the lesser curvature. The gastric mucosa is grossly unremarkable. On examining the specimen for lymph node, a tan-white to tan-red lymph node (peri-bile duct area) is present measuring 1.5 cm in greatest dimensions. Sectioning the perigastric omental soft tissue, multiple single lymph

[page 6 of 6]
nodes are grossly identified ranging in sizes from 0.2 mm to 0.5 cm in greatest dimensions. Representative fresh tissue is submitted to Tissue Procurement Laboratory. Representative sections are submitted as follows:

- FSM1: Tangential pancreatic duct margin of resection
- FSM2: Cystic duct margin of resection
- M3: Perpendicular section posterior surface of resection
- M4: Tangential proximal stomach margin of resection
- M5: Tangential distal duodenal margin of resection
- M6-M7: Perpendicular section portal vein margin of resection in relation to the tumor
- M8: Perpendicular section superior mesenteric artery margin of resection
- M9: Tumor in relation to bile duct
- M10: Tumor in relation to bile duct
- M11: Representative section of ampulla of Vater
- M12-M13: Tumor in relation to duodenal mucosa
- M14-M17: Entire peripancreatic fat tissue
- M18: Lymph node bisected bile duct area
- M19: Un-involved pancreatic tissue
- M20: Normal gastric mucosa
- M21: Normal duodenal mucosa
- M22-M33: Multiple single lymph nodes and fibroadipose tissue (omental fat)

Source: NCI Genomic Data Commons file 2da62b78-3aad-433e-8df8-a2a716c3ea14 (TCGA-3A-A9IZ.F6EEF42B-567E-4B13-A155-AD8DDFF9A0C6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).